Somatic mutation profile of tumor specimen ALCH-B1RS-TTP1-A (aliquot ALCH-B1RS-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1RS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.2 years (26,745 days).
Specimen ALCH-B1RS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612d7f76-7fc4-489f-aad8-7c53279eddfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RS-NB1-A (Blood Derived Normal), aliquot ALCH-B1RS-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a3d5f76-d959-47da-b9fd-8dc69a4d9fe2

The open-access MAF lists 101 somatic variants for this specimen: 70 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 19, Intron 6, Nonsense Mutation 4, Splice Site 3, RNA 3, In Frame Del 1, 3'UTR 1, Translation Start Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 34/460 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- BTBD7 | c.1353C>G p.I451M | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs556272784; called by muse, mutect2
- CER1 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.923); catalogued as rs759414494; called by muse, mutect2
- DNAH10 | c.902C>A p.A301D (on ENST00000409039; = p.A240D on NM_207437.3) | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV68996927; called by muse, mutect2
- FABP12 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100846577; called by muse, mutect2
- HDC | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 28/808 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0.129); catalogued as COSV99983929; called by muse, mutect2
- LTBP1 | c.2418G>T p.K806N (on ENST00000404816 / NM_206943.4; = p.K480N on NM_000627.4) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs1362571894; called by muse, mutect2
- OR2L13 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.572); catalogued as COSV63557351; called by muse, mutect2
- OR2W3 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64457105; called by muse, mutect2
- PCDH17 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64974101; called by muse, mutect2
- PCDHGB4 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1323439261, COSV54023214, COSV99527950; called by muse, mutect2
- PPP4R3C | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.217); catalogued as COSV69081141; called by muse, mutect2
- PRKCB | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57798914; called by muse, mutect2
- RHBDD3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1273519743; called by muse, mutect2, varscan2
- SPANXD | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 28/805 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV65152384; called by muse, mutect2
- SPATA31D1 | c.1501G>C p.V501L | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs1467167364, COSV61199517; called by muse, mutect2
- TBX22 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64786710; called by muse, mutect2
- TRPC4 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58997624; called by muse, mutect2
- ZNF160 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 16/214 reads (7%) | catalogued as rs866611413, COSV61999647; called by muse, mutect2
- AC244197.3 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AFAP1 | c.140A>T p.K47M | Missense Mutation (SNP) | VAF 27/493 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2
- AMER3 | c.2562_2576del p.A855_P859del | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ATXN7L1 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.907); called by muse, mutect2
- B3GALT2 | c.1101G>C p.W367C | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- BRIP1 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 17/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BTBD3 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 30/1012 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- BTBD8 | c.3148G>C p.D1050H (on ENST00000636805 / NM_001376131.1; = p.D537H on NM_015237.4) | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- CACNA1F | c.5290G>T p.G1764W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CDH23 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CDK18 | c.622G>C p.E208Q (on ENST00000506784 / NM_212503.3; = p.E178Q on NM_002596.4) | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- CES3 | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- CNGA4 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CNTNAP5 | c.349T>A p.W117R | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COPS9 | c.94T>G p.L32V (on ENST00000607357 / NM_001163424.2; = p.L63V on NM_138336.1) | Missense Mutation (SNP) | VAF 14/371 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- COQ8B | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.026); called by muse, mutect2
- CPNE4 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDB2 | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DNAH6 | c.8652G>T p.W2884C | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESRRG | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FUZ | c.780T>A p.Y260* | Nonsense Mutation (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- GABRA4 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 19/466 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.342); called by muse, mutect2
- HOXC10 | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2
- LARP1B | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 28/615 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- MSC-AS1 | n.310-1G>T | Splice Site (SNP) | VAF 24/422 reads (6%) | called by muse, mutect2
- MTMR8 | c.605T>A p.I202N | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC12 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MYH1 | c.1417T>A p.F473I | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- MYT1 | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); called by muse, mutect2
- NLRC4 | c.677C>A p.T226K | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.029); called by muse, mutect2
- OR1L4 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 30/624 reads (5%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.946); called by muse, mutect2
- OSTN | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- PASD1 | c.2088G>T p.L696F | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PKP1 | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 21/490 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- PRKCB | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SASH3 | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCLT1 | c.1330A>G p.R444G | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); called by muse, mutect2
- SERPINA6 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SH3TC2 | c.2444C>A p.A815D | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SLC25A25 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/87 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- SLIT3 | c.342-2A>G p.X114_splice | Splice Site (SNP) | VAF 18/498 reads (4%) | called by muse, mutect2
- STRN3 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- STXBP5L | c.2181G>C p.Q727H | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- SUPT20HL1 | c.2399C>G p.P800R | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.435); called by muse, mutect2
- TARBP1 | c.1900A>T p.K634* | Nonsense Mutation (SNP) | VAF 26/481 reads (5%) | called by muse, mutect2
- TP63 | c.1340T>A p.L447H | Missense Mutation (SNP) | VAF 24/651 reads (4%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.984); called by muse, mutect2
- TRPM8 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- UGT2B27P | n.1039-1A>G | Splice Site (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- WBP2 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2
- WDR86 | c.635G>T p.S212I | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF787 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.353); called by muse, varscan2
- BACH2 | c.210A>G p.T70= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- DOCK10 | c.2082G>T p.R694= | Silent (SNP) | VAF 11/340 reads (3%) | called by muse, mutect2
- DOCK2 | c.2595G>T p.L865= | Silent (SNP) | VAF 18/327 reads (6%) | called by muse, mutect2
- GPSM1 | c.1110G>T p.T370= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs782019773; called by muse, mutect2
- GRID2 | c.1731C>A p.V577= | Silent (SNP) | VAF 26/699 reads (4%) | called by muse, mutect2
- IFNA8 | c.120C>A p.L40= | Silent (SNP) | VAF 26/423 reads (6%) | called by muse, mutect2
- IGKV2D-26 | c.69G>T p.V23= | Silent (SNP) | VAF 11/296 reads (4%) | called by muse, mutect2
- INA | c.960G>A p.Q320= | Silent (SNP) | VAF 10/171 reads (6%) | catalogued as rs1169073593; called by muse, mutect2
- INSL4 | c.210C>T p.T70= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- LHX4 | c.84C>T p.P28= | Silent (SNP) | VAF 25/406 reads (6%) | catalogued as COSV55373674; called by muse, mutect2
- LRP1B | c.2118C>T p.T706= | Silent (SNP) | VAF 15/515 reads (3%) | catalogued as rs1305804010; called by muse, mutect2
- MACF1 | c.10149G>T p.R3383= | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- OGDHL | c.1428G>A p.V476= | Silent (SNP) | VAF 6/162 reads (4%) | called by muse, mutect2
- PLEKHB2 | c.444C>G p.P148= | Silent (SNP) | VAF 26/573 reads (5%) | called by muse, mutect2
- PTK2B | c.294G>A p.K98= | Silent (SNP) | VAF 16/383 reads (4%) | called by muse, mutect2
- TMPRSS11B | c.312T>A p.P104= | Silent (SNP) | VAF 18/474 reads (4%) | called by muse, mutect2
- WSCD1 | c.214C>T p.L72= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as rs751981355; called by muse, mutect2
- ZDHHC15 | c.6G>C p.R2= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- ZP2 | c.1053C>T p.S351= | Silent (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- CA1 | c.*43T>A | 3'UTR (SNP) | VAF 8/244 reads (3%) | called by muse, mutect2
- FGF3 | c.-17G>T | 5'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- GPX4 | chr19:1103981 C>T | 5'Flank (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- GVINP1 | n.4574G>A | RNA (SNP) | VAF 9/264 reads (3%) | called by muse, mutect2
- KRT8P11 | n.358T>A | RNA (SNP) | VAF 21/640 reads (3%) | called by muse, mutect2
- NTRK3 | c.2133+12680C>A | Intron (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- PLA2G6 | c.1077+667G>T | Intron (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+3795C>T | Intron (SNP) | VAF 26/481 reads (5%) | catalogued as rs374214352, COSV100664525; called by muse, mutect2
- SLC19A2 | c.1224-44C>A | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- SLC25A16 | c.842+14A>C | Intron (SNP) | VAF 9/229 reads (4%) | called by muse, mutect2
- SSPOP | n.15359C>A | RNA (SNP) | VAF 17/424 reads (4%) | called by muse, mutect2
- ZEB2 | c.73+4683T>A | Intron (SNP) | VAF 19/405 reads (5%) | called by muse, mutect2
